Somatic mutation profile of tumor specimen 0DFRU6 from CCDI case PBBSPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,259 days).
Specimen 0DFRU6: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 325d3533-4b7a-435b-afb4-af9806789e68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFRU7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc6321c3-b699-4303-97ee-52f73449311f

The open-access MAF lists 36 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 10, Silent 4, 3'UTR 3, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TNNI3 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs727503499, CM113585, COSV52572608; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by muse, mutect2
- ANTXR2 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 37/511 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs919099773, COSV56313408; called by muse, mutect2
- LATS2 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV66874025; called by muse, mutect2, varscan2
- MUC17 | c.5665A>T p.T1889S | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100073264; called by muse, mutect2, varscan2
- MYO7A | c.4400C>A p.P1467H | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149624; called by muse, mutect2, varscan2
- OR10S1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139111775, COSV101602469; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, varscan2
- SLC35C1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1292731061, COSV100029369; called by muse, mutect2, varscan2
- ACOX2 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ATP2A3 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CTNNA2 | c.446T>A p.L149H | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEPDC1 | c.1165A>G p.R389G | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- FAM184B | c.1694+1G>T p.X565_splice | Splice Site (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- MXRA5 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, varscan2
- PRRC2A | c.4775C>T p.P1592L | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- SMDT1 | c.268G>C p.A90P | Missense Mutation (SNP) | VAF 58/494 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TNRC6A | c.4519G>A p.A1507T | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ABCA7 | c.2835A>G p.Q945= | Silent (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs1167537044; called by muse, mutect2, varscan2
- CROCC | c.1935A>G p.E645= | Silent (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- FTH1 | c.12G>A p.A4= | Silent (SNP) | VAF 32/521 reads (6%) | called by muse, mutect2
- ARFGEF2 | c.3222-64A>G | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, varscan2
- BFAR | c.638+77C>T | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as rs1247276679; called by muse, varscan2
- CALML4 | c.305-54T>C | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 24/223 reads (11%) | called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99987084; called by muse, varscan2
- L3MBTL2 | c.*46G>A | 3'UTR (SNP) | VAF 20/197 reads (10%) | catalogued as rs367897147; called by muse, mutect2, varscan2
- MKS1 | c.262-89T>C | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- MKS1 | c.262-90G>A | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs1289531751; called by mutect2, varscan2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- PRRG4 | c.*62T>C | 3'UTR (SNP) | VAF 14/155 reads (9%) | catalogued as rs1283154682; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 12/118 reads (10%) | called by muse, varscan2
- ROPN1L | c.593+84C>G | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, varscan2
- USP40 | c.2381-58G>T | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, varscan2
- ZCRB1 | c.334-69A>T | Intron (SNP) | VAF 20/104 reads (19%) | called by muse, varscan2
